Somatic mutation profile of tumor specimen C3N-01220-02 (aliquot CPT0076330006) from CPTAC case C3N-01220, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 51.3 years (18,748 days).
Specimen C3N-01220-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e1477df-4e1d-4f33-a66f-2e05d86eb986.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01220-71 (Blood Derived Normal), aliquot CPT0076400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a4c1948-2d78-44e0-8ee7-ad658cd3de21

The open-access MAF lists 88 somatic variants for this specimen: 52 protein-altering or splice-affecting, 24 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 24, Intron 7, Nonsense Mutation 4, Splice Site 4, Frame Shift Del 2, RNA 2, 5'UTR 1, 3'UTR 1, In Frame Del 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4715+1G>T p.X1572_splice | Splice Site (SNP) | VAF 11/45 reads (24%) | hotspot (GDC flag); catalogued as COSV57431126, COSV57439397; called by muse, mutect2
- TGFBR2 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 26/412 reads (6%) | catalogued as rs863223852, CM063204, COSV55443474; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- AFF4 | c.935A>G p.D312G | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs751474496; called by muse, mutect2, varscan2
- ANK2 | c.11333G>A p.G3778E | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.943); catalogued as COSV52147199, COSV52178677; called by muse, mutect2, varscan2
- ANKRD34B | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 13/97 reads (13%) | catalogued as COSV58613404; called by muse, mutect2, varscan2
- ANO2 | c.2363C>T p.P788L (on ENST00000356134 / NM_001278597.3; = p.P792L on NM_001278596.3) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370114605; called by muse, mutect2, varscan2
- ARHGAP23 | c.2439C>G p.D813E | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as rs1049336617; called by muse, mutect2, varscan2
- CLCN1 | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 44/356 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1473430259, COSV58368059; ClinVar: uncertain significance; called by muse, varscan2
- DOCK1 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); catalogued as COSV54728364; called by muse, mutect2, varscan2
- FGD5 | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV53240622; called by muse, mutect2, varscan2
- FNIP1 | c.2338C>T p.H780Y | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.253); catalogued as rs756786251; called by muse, mutect2
- HMMR | c.508T>A p.L170M | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100700997; called by muse, mutect2, varscan2
- IQGAP3 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63254652; called by muse, mutect2, varscan2
- KANSL3 | c.2210C>G p.P737R (on ENST00000666923 / NM_001349262.2; = p.P711R on NM_001115016.3) | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs954265164; called by muse, mutect2, varscan2
- KCTD15 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 12/135 reads (9%) | catalogued as rs757471584, COSV52289992; called by muse, mutect2, varscan2
- KLHL33 | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1363315688; called by muse, mutect2, varscan2
- MYH3 | c.645G>C p.G215= | Splice Region (SNP) | VAF 51/382 reads (13%) | catalogued as COSV56862257; called by muse, mutect2, varscan2
- PCBP1 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 51/385 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs368303566; called by muse, mutect2, varscan2
- QARS1 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs62621222; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPHK2 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 23/430 reads (5%) | catalogued as rs758872660, COSV99709238; called by muse, mutect2
- TJP2 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 38/383 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142684074, COSV55271491; ClinVar: uncertain significance; called by muse, mutect2
- UGGT1 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs1181179801; called by muse, mutect2
- UNC13D | c.2074G>A p.G692S | Missense Mutation (SNP) | VAF 117/1100 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99256156; called by muse, mutect2, varscan2
- ZNF638 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as COSV52485440; called by muse, mutect2, varscan2
- ACAD9 | c.227A>C p.K76T | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2
- ARHGAP12 | c.2139G>T p.L713F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ARHGEF33 | c.1221+1del | Frame Shift Del (DEL) | VAF 19/126 reads (15%) | called by mutect2, pindel, varscan2
- CORIN | c.1736-12_1738del p.X579_splice | Splice Site (DEL) | VAF 20/145 reads (14%) | called by mutect2, pindel
- DOC2A | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 101/730 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK1 | c.549T>A p.S183R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ELOVL7 | c.256-1G>C p.X86_splice | Splice Site (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- EPS8 | c.496T>C p.F166L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HAS3 | c.442T>G p.F148V | Missense Mutation (SNP) | VAF 112/701 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HELQ | c.3238G>T p.V1080L | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- KCNG1 | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP6 | c.3294del p.F1098Lfs*4 | Frame Shift Del (DEL) | VAF 20/188 reads (11%) | called by mutect2, pindel
- MICU3 | c.1503C>A p.D501E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.712); called by mutect2, varscan2
- MYH13 | c.2283G>T p.R761S | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- PIK3R1 | c.1715_1718delinsC p.Q572_L573delinsP (on ENST00000521381 / NM_181523.3; = p.Q302_L303delinsP on NM_181504.4) | In Frame Del (DEL) | VAF 9/61 reads (15%) | called by pindel, varscan2*
- PIK3R4 | c.1718C>G p.A573G | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- RECK | c.241A>C p.I81L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RPS6KB1 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, varscan2
- SFMBT2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SLC44A1 | c.726G>T p.W242C | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2
- SPATA5 | c.1999T>A p.Y667N | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPIN3 | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPPL2A | c.361-1G>T p.X121_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | called by mutect2, varscan2
- STK36 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- TAZ | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TWF1 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- VN1R1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- YEATS2 | c.3754G>A p.D1252N | Missense Mutation (SNP) | VAF 62/424 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- AL592490.1 | c.60G>A p.A20= | Silent (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- CDC25B | c.1134C>T p.H378= (on ENST00000245960 / NM_021873.3; = p.H364= on NM_004358.4) | Silent (SNP) | VAF 44/211 reads (21%) | catalogued as rs560679507, COSV99848466; called by muse, varscan2
- COL11A1 | c.1512C>A p.S504= | Silent (SNP) | VAF 50/256 reads (20%) | called by muse, mutect2, varscan2
- CSMD2 | c.5190C>A p.T1730= | Silent (SNP) | VAF 49/399 reads (12%) | called by muse, mutect2, varscan2
- DDX11 | c.1737C>T p.D579= | Silent (SNP) | VAF 93/568 reads (16%) | catalogued as rs755996490; called by muse, mutect2, varscan2
- EPYC | c.249A>G p.E83= | Silent (SNP) | VAF 13/133 reads (10%) | called by muse, mutect2
- FBXW12 | c.1392G>A p.T464= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs749755227, COSV56483295; called by muse, mutect2, varscan2
- FNDC11 | c.549C>T p.H183= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs1352060707; called by muse, mutect2, varscan2
- KCNG1 | c.1336C>T p.L446= | Silent (SNP) | VAF 36/209 reads (17%) | called by muse, mutect2, varscan2
- KIAA0930 | c.324C>G p.L108= (on ENST00000336156 / NM_001009880.2; = p.L113= on NM_015264.2) | Silent (SNP) | VAF 35/239 reads (15%) | called by muse, mutect2, varscan2
- KIF3C | c.1203G>T p.G401= | Silent (SNP) | VAF 36/235 reads (15%) | called by muse, mutect2, varscan2
- LILRB2 | c.24G>C p.L8= | Silent (SNP) | VAF 29/249 reads (12%) | called by muse, mutect2, varscan2
- LRP2 | c.9798C>T p.N3266= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as rs1481482183; called by muse, mutect2, varscan2
- MAPK8IP2 | c.711C>T p.S237= | Silent (SNP) | VAF 26/159 reads (16%) | catalogued as rs1429065925; called by muse, mutect2, varscan2
- MYOT | c.207C>T p.F69= | Silent (SNP) | VAF 30/220 reads (14%) | called by muse, mutect2, varscan2
- PAPSS2 | c.789C>T p.G263= | Silent (SNP) | VAF 77/487 reads (16%) | called by muse, mutect2, varscan2
- PCDH15 | c.5124A>G p.P1708= | Silent (SNP) | VAF 39/264 reads (15%) | called by muse, mutect2, varscan2
- PLEC | c.10155C>T p.G3385= (on ENST00000322810 / NM_201380.4; = p.G3275= on NM_000445.5) | Silent (SNP) | VAF 98/768 reads (13%) | called by muse, mutect2, varscan2
- SFTPD | c.183C>T p.G61= | Silent (SNP) | VAF 40/311 reads (13%) | catalogued as rs148973610; called by muse, mutect2, varscan2
- SLC7A3 | c.120G>T p.L40= | Silent (SNP) | VAF 59/203 reads (29%) | catalogued as COSV99979501; called by muse, mutect2, varscan2
- SMTNL2 | c.291C>T p.P97= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs1020958547; called by muse, mutect2, varscan2
- SYMPK | c.234C>T p.I78= | Silent (SNP) | VAF 52/322 reads (16%) | catalogued as rs188023108, COSV55615073; called by muse, mutect2, varscan2
- WDR1 | c.1377G>A p.T459= (on ENST00000382452; = p.T319= on NM_005112.5) | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as rs754699425, COSV101221170; called by muse, mutect2, varscan2
- ZNF143 | c.1641G>A p.T547= | Silent (SNP) | VAF 39/241 reads (16%) | catalogued as rs572827042, COSV55182215; called by muse, mutect2, varscan2
- ALK | c.3516-162_3516-161insAAGAT | Intron (INS) | VAF 28/156 reads (18%) | called by mutect2, varscan2*
- ARL13B | c.*786T>G | 3'UTR (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- CTDSP1 | c.68-669C>A | Intron (SNP) | VAF 38/518 reads (7%) | called by muse, mutect2
- CTSA | c.195-42G>T | Intron (SNP) | VAF 66/439 reads (15%) | called by muse, mutect2, varscan2
- FAM24B | chr10:122883863 G>A | 5'Flank (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- MAP2K3 | c.49+3102G>A | Intron (SNP) | VAF 29/372 reads (8%) | catalogued as rs1403589133; called by muse, mutect2
- MYH9 | c.5592+16G>T | Intron (SNP) | VAF 83/644 reads (13%) | called by muse, mutect2, varscan2
- S1PR3 | c.-148+192C>T | Intron (SNP) | VAF 143/897 reads (16%) | catalogued as rs774548704; called by muse, mutect2, varscan2
- SAYSD1 | c.208-3542T>G | Intron (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2, varscan2
- SMIM8 | n.522G>A | RNA (SNP) | VAF 18/126 reads (14%) | catalogued as rs1206953256; called by mutect2, varscan2
- TPR | c.-103G>C | 5'UTR (SNP) | VAF 20/214 reads (9%) | called by muse, mutect2
- ZNF658B | n.865A>T | RNA (SNP) | VAF 27/214 reads (13%) | called by muse, mutect2, varscan2
